Somatic mutation profile of tumor specimen TCGA-CW-5580-01A (aliquot TCGA-CW-5580-01A-01D-1669-08) from TCGA case TCGA-CW-5580, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 73.1 years (26,696 days).
Specimen TCGA-CW-5580-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5228b0b5-3a85-42b9-b990-a95eee681e3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CW-5580-11A (Solid Tissue Normal), aliquot TCGA-CW-5580-11A-02D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73be4e43-b0fc-4ddd-80d1-718a5f1d708f

The open-access MAF lists 111 somatic variants for this specimen: 75 protein-altering or splice-affecting, 34 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 34, Frame Shift Del 12, Splice Site 4, Nonsense Mutation 2, Frame Shift Ins 1, Intron 1, In Frame Del 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.7500T>G p.I2500M | Missense Mutation (SNP) | VAF 31/142 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1057519915, COSV63869436; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1661C>T p.P554L (on ENST00000373993 / NM_138932.2; = p.P546L on NM_014576.4) | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV51054244; called by muse, mutect2, varscan2
- ABCB8 | c.254C>A p.P85H (on ENST00000297504 / NM_001282291.2; = p.P68H on NM_007188.5) | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.533); catalogued as rs1241101491, COSV52511383; called by muse, mutect2
- AMER1 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV57660555; called by muse, mutect2, varscan2
- ARSB | c.448A>T p.M150L | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.169); catalogued as COSV53730052; called by muse, mutect2
- ATF7IP2 | c.287T>G p.I96R | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV61095683; called by muse, mutect2, varscan2
- ATP10A | c.2031G>A p.W677* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as rs372456477, COSV63516367, COSV63518011; called by muse, mutect2, varscan2
- BAP1 | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1060503745, COSV56241754; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4700T>C p.V1567A | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as COSV63247786; called by muse, mutect2, varscan2
- CLASP1 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV55343075; called by muse, mutect2, varscan2
- CLCN2 | c.2171T>C p.L724P | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.486); catalogued as COSV55604845; called by muse, mutect2, varscan2
- CNGA1 | c.449A>T p.E150V | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV62057344; called by muse, mutect2, varscan2
- CNTRL | c.2294A>T p.E765V | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV53054495; called by muse, mutect2, varscan2
- CPSF3 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.457); catalogued as COSV53012335; called by muse, mutect2, varscan2
- CUL7 | c.523T>G p.Y175D | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.621); catalogued as COSV54822979; called by muse, mutect2, varscan2
- DHX37 | c.2491A>G p.S831G | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199731932, COSV58140002; called by muse, mutect2
- DNAH8 | c.10807-1G>A p.X3603_splice | Splice Site (SNP) | VAF 17/397 reads (4%) | catalogued as rs1228447447, COSV59485334; called by muse, mutect2
- DNAH9 | c.8342T>C p.L2781P | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52375649; called by muse, mutect2, varscan2
- DNAH9 | c.12191G>A p.R4064K | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52380723; called by muse, mutect2, varscan2
- ECHS1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs1426014295, CM156464, COSV63907616; called by muse, mutect2, varscan2
- EPB41L3 | c.2278T>A p.S760T | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as rs1181117662, COSV59470472; called by muse, mutect2, varscan2
- GALNT17 | c.1703G>A p.C568Y | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61196182; called by muse, mutect2, varscan2
- GALNTL5 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV67181436; called by muse, mutect2, varscan2
- GATA2 | c.638A>T p.Y213F | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.908); catalogued as COSV62007768; called by muse, mutect2, varscan2
- GPR149 | c.425C>A p.T142K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV67665904; called by muse, mutect2, varscan2
- GRIA1 | c.2176A>T p.I726F | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV53627922; called by muse, mutect2, varscan2
- GRIA3 | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 19/305 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1230902081, COSV52083076; called by muse, mutect2
- GRIK2 | c.2390A>G p.K797R | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.957); catalogued as COSV59778310; called by muse, mutect2, varscan2
- HASPIN | c.2312A>G p.K771R | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV54000986; called by muse, mutect2, varscan2
- HCCS | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772248528, COSV58239739; called by muse, mutect2, varscan2
- HNF1B | c.906C>G p.N302K | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as CM104910; called by muse, mutect2, varscan2
- IFT140 | c.3620T>A p.L1207Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63699504; called by muse, mutect2
- ITGB4 | c.2448G>A p.V816= | Splice Region (SNP) | VAF 17/54 reads (31%) | catalogued as COSV52334193; called by muse, mutect2, varscan2
- KASH5 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs769812920, COSV71358579; called by muse, mutect2, varscan2
- LCMT2 | c.1091T>C p.F364S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV59792014; called by muse, mutect2, varscan2
- LRCH3 | c.941A>G p.N314S | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.872); catalogued as rs773418585, COSV58397383; called by muse, mutect2, varscan2
- MAP3K15 | c.3400+2T>G p.X1134_splice | Splice Site (SNP) | VAF 46/180 reads (26%) | catalogued as COSV58840163; called by muse, mutect2, varscan2
- MUC5B | c.13282G>A p.A4428T | Missense Mutation (SNP) | VAF 111/319 reads (35%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV71593684; called by muse, mutect2, varscan2
- NOC4L | c.1094T>C p.V365A | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.26); catalogued as COSV57960432; called by muse, mutect2, varscan2
- NUP58 | c.1011T>G p.H337Q | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV101098834, COSV67752208; called by muse, mutect2, varscan2
- OR1E1 | c.592del p.V198* | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as COSV100492024; called by mutect2, pindel, varscan2
- OR7A5 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as COSV59235770; called by muse, mutect2, varscan2
- PLXND1 | c.3973+1G>A p.X1325_splice | Splice Site (SNP) | VAF 20/50 reads (40%) | catalogued as COSV60720192; called by muse, mutect2, varscan2
- PTAR1 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as COSV61209725; called by muse, mutect2, varscan2
- PTCHD1 | c.1933T>C p.S645P | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65063209; called by muse, mutect2
- RDH11 | c.763T>C p.F255L | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs182091562, COSV67283450; called by muse, mutect2, varscan2
- RIMKLA | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV68910030, COSV68910063; called by muse, mutect2, varscan2
- RPN2 | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52909488; called by muse, mutect2, varscan2
- SCG2 | c.1232C>A p.S411Y | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV59542072; called by muse, mutect2, varscan2
- SCN3A | c.4361T>C p.F1454S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs1305936001, COSV51827150; called by muse, mutect2, varscan2
- SECISBP2L | c.2100C>A p.F700L (on ENST00000559471 / NM_001193489.2; = p.F655L on NM_014701.4) | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV55938531; called by muse, mutect2, varscan2
- SETD2 | c.4102C>T p.Q1368* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV57432580; called by muse, mutect2, varscan2
- ST7L | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58312676; called by muse, mutect2, varscan2
- SUPT7L | c.983G>C p.S328T | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV53118077; called by muse, mutect2, varscan2
- SYNC | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 152/562 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65131615; called by muse, mutect2, varscan2
- TENM1 | c.4209del p.I1404Ffs*16 | Frame Shift Del (DEL) | VAF 28/128 reads (22%) | catalogued as COSV64440685; called by mutect2, pindel, varscan2
- TRIP11 | c.167A>C p.E56A | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV50971010; called by muse, mutect2, varscan2
- TTN | c.85986C>A p.N28662K (on ENST00000591111; = p.N21238K on NM_003319.4) | Missense Mutation (SNP) | VAF 12/142 reads (8%) | PolyPhen probably damaging (0.997); catalogued as COSV60397649; called by muse, mutect2
- USP33 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs780237602, COSV62471817; called by muse, mutect2, varscan2
- VHL | c.388G>T p.V130F | Missense Mutation (SNP) | VAF 76/156 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104893830, CM031394, CM126148, CM961427, COSV56543368, COSV56544519, COSV56551325, COSV56566091; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- VPS37A | c.243T>G p.S81R | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.994); catalogued as COSV61353596; called by muse, mutect2, varscan2
- ZNF107 | c.1297del p.I433Ffs*84 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as COSV61329354; called by mutect2, pindel, varscan2
- ZNF419 | c.1329G>A p.M443I | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55657909; called by muse, mutect2, varscan2
- BANK1 | c.1008_1009+4del p.X336_splice | Splice Site (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel
- DENND5B | c.3759del p.L1254Cfs*9 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- DPH7 | c.1227del p.W409Cfs*14 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, varscan2
- ETAA1 | c.2689_2707del p.E897Kfs*16 | Frame Shift Del (DEL) | VAF 49/244 reads (20%) | called by mutect2, pindel, varscan2
- HNRNPA1 | c.673_676+2del | In Frame Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel
- IFT172 | c.856_859del p.L286Tfs*42 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by mutect2, pindel, varscan2
- MEMO1 | c.416_423delinsGGA p.Y139Wfs*8 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | called by pindel, varscan2*
- PBRM1 | c.4601del p.P1534Hfs*5 (on ENST00000296302 / NM_001366071.2; = p.P1427Hfs*5 on NM_018313.5) | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | called by mutect2, pindel, varscan2
- PCNX4 | c.3285_3286del p.R1095Sfs*3 (on ENST00000406854 / NM_001330177.2; = p.R861Sfs*3 on NM_022495.5) | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by pindel, varscan2
- RRP15 | c.741_754del p.I248Ffs*15 | Frame Shift Del (DEL) | VAF 14/100 reads (14%) | called by mutect2, pindel, varscan2
- TRIM33 | c.2533dup p.M845Nfs*3 | Frame Shift Ins (INS) | VAF 39/153 reads (25%) | called by mutect2, pindel, varscan2
- WASHC3 | c.397del p.D133Ifs*17 | Frame Shift Del (DEL) | VAF 62/248 reads (25%) | called by mutect2, pindel, varscan2
- AAR2 | c.369G>C p.G123= | Silent (SNP) | VAF 34/139 reads (24%) | catalogued as COSV57925127; called by muse, mutect2, varscan2
- ACADVL | c.726C>T p.T242= | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as COSV50040080; called by muse, mutect2, varscan2
- ACIN1 | c.1164C>A p.S388= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV52983002; called by muse, mutect2
- C16orf78 | c.129G>A p.G43= | Silent (SNP) | VAF 10/117 reads (9%) | catalogued as rs756344768, COSV54558866; called by muse, mutect2
- CA4 | c.199C>T p.L67= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as COSV56283010; called by muse, mutect2, varscan2
- COPA | c.93G>T p.G31= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as rs897906684, COSV54110431; called by muse, mutect2, varscan2
- DCAF12L1 | c.96C>T p.D32= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as rs1186246698, COSV64421377; called by muse, mutect2, varscan2
- DDX53 | c.1647C>T p.D549= | Silent (SNP) | VAF 37/227 reads (16%) | catalogued as rs768020057, COSV60068768; called by muse, mutect2, varscan2
- DMXL1 | c.8265T>C p.T2755= | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as COSV60722522; called by muse, mutect2, varscan2
- EHD1 | c.78G>A p.R26= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV57737142; called by muse, mutect2, varscan2
- EIF3B | c.1077A>G p.L359= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as COSV62805387; called by muse, mutect2, varscan2
- EPG5 | c.3900C>T p.V1300= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as COSV56357067; called by muse, varscan2
- EPHB6 | c.2877A>T p.S959= | Silent (SNP) | VAF 6/148 reads (4%) | catalogued as COSV63890286, COSV63894060; called by muse, mutect2
- GALNT17 | c.1704C>T p.C568= | Silent (SNP) | VAF 46/156 reads (29%) | catalogued as COSV61196196; called by muse, mutect2, varscan2
- GRIN3A | c.2904G>A p.K968= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as rs774242537, COSV62459210; called by muse, mutect2, varscan2
- ITGAX | c.1395G>A p.V465= | Silent (SNP) | VAF 16/182 reads (9%) | catalogued as COSV51652505; called by muse, mutect2
- KIR3DL2 | c.717C>T p.N239= | Silent (SNP) | VAF 24/314 reads (8%) | catalogued as rs1291644730; called by muse, mutect2
- LILRB5 | c.535C>T p.L179= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as COSV60261600; called by muse, mutect2, varscan2
- MAN2A2 | c.846C>A p.P282= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV64640194; called by muse, mutect2, varscan2
- MC3R | c.471C>A p.T157= | Silent (SNP) | VAF 48/155 reads (31%) | catalogued as rs764841394, COSV54764350, COSV54765239; called by muse, mutect2, varscan2
- MUC4 | c.9G>A p.G3= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV62204329; called by muse, mutect2, varscan2
- NOS3 | c.1177C>T p.L393= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV52496791; called by muse, mutect2
- OR3A1 | c.396C>T p.P132= | Silent (SNP) | VAF 33/127 reads (26%) | catalogued as COSV60163962; called by muse, mutect2, varscan2
- PPFIBP1 | c.1263T>C p.T421= (on ENST00000318304 / NM_177444.3; = p.T404= on NM_003622.4) | Silent (SNP) | VAF 48/116 reads (41%) | catalogued as COSV57299758; called by muse, mutect2, varscan2
- RARB | c.9C>A p.T3= | Silent (SNP) | VAF 38/91 reads (42%) | called by muse, mutect2, varscan2
- RARS1 | c.882A>T p.V294= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV51566469; called by muse, mutect2
- RASAL2 | c.2559A>G p.R853= | Silent (SNP) | VAF 4/77 reads (5%) | catalogued as COSV62724681; called by muse, mutect2
- RTL5 | c.903T>A p.I301= | Silent (SNP) | VAF 24/326 reads (7%) | catalogued as COSV65455301; called by muse, mutect2
- SLC7A14 | c.1794C>T p.I598= | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as COSV51588887; called by muse, mutect2, varscan2
- STAB2 | c.2667C>T p.G889= | Silent (SNP) | VAF 59/200 reads (30%) | catalogued as COSV66348427; called by muse, mutect2, varscan2
- WWC3 | c.1239C>T p.F413= | Silent (SNP) | VAF 22/187 reads (12%) | catalogued as rs148094144, COSV66508521; called by muse, mutect2, varscan2
- XDH | c.1527C>T p.C509= | Silent (SNP) | VAF 50/136 reads (37%) | catalogued as COSV65151488; called by muse, mutect2, varscan2
- YLPM1 | c.1755A>T p.A585= | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as COSV53122236; called by muse, mutect2, varscan2
- ZNF354B | c.91C>T p.L31= | Silent (SNP) | VAF 37/125 reads (30%) | catalogued as COSV59367728; called by muse, varscan2
- ANKMY1 | c.-122+661C>T | Intron (SNP) | VAF 12/131 reads (9%) | catalogued as rs756434459, COSV56042208; called by muse, mutect2, varscan2
- CCDC144B | n.510C>T | RNA (SNP) | VAF 11/34 reads (32%) | called by mutect2, varscan2
